Somatic mutation profile of tumor specimen TCGA-17-Z009-01A (aliquot TCGA-17-Z009-01A-01W-0746-08) from TCGA case TCGA-17-Z009, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z009-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 496f2027-253d-4c6f-a7db-db576af1d8fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z009-11A (Solid Tissue Normal), aliquot TCGA-17-Z009-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3fc6691-992d-48cf-a376-9a122ae0c992

The open-access MAF lists 40 somatic variants for this specimen: 33 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 5, Frame Shift Ins 1, RNA 1, Splice Site 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7A | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs1557231860; called by muse, mutect2
- DCAF4L2 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV60476952, COSV60481637; called by mutect2, varscan2
- DCX | c.932G>T p.G311V (on ENST00000636035 / NM_001195553.2; = p.X311_splice on NM_000555.3) | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV57568945, COSV57574514; called by muse, mutect2
- DCX | c.931G>T p.G311C (on ENST00000636035 / NM_001195553.2; = p.A311S on NM_000555.3) | Missense Mutation (SNP) | VAF 31/398 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as COSV100576764, COSV57576133; called by muse, mutect2
- OR5D14 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59456295, COSV99045924; called by mutect2, varscan2
- PIKFYVE | c.3835G>T p.V1279L | Missense Mutation (SNP) | VAF 27/500 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.97); catalogued as COSV52239043; called by muse, mutect2
- PTPRN2 | c.619G>T p.G207W | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.68); catalogued as rs141244412; called by muse, mutect2, varscan2
- SLC39A12 | c.969G>T p.K323N | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66194832, COSV66201234; called by muse, mutect2
- UBE2E3 | c.588G>T p.R196S | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV66585530; called by muse, mutect2
- VPS41 | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.723); catalogued as COSV59645547; called by muse, mutect2
- ABCE1 | c.584A>G p.K195R | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.102); called by muse, mutect2
- ADAM29 | c.826A>G p.N276D | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.872); called by muse, mutect2
- ADGRD1 | c.1807C>T p.H603Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2
- CLEC12A | c.41A>G p.N14S | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.13); called by muse, mutect2
- DCLK3 | c.1471A>C p.K491Q | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.063); called by muse, mutect2
- FOXO1 | c.711G>T p.W237C | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRTAP10-6 | c.558C>A p.C186* | Nonsense Mutation (SNP) | VAF 18/324 reads (6%) | called by muse, mutect2
- LRP1B | c.5105C>A p.P1702Q | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MFAP3L | c.307C>A p.Q103K | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- MYO5A | c.757-1G>A p.X253_splice | Splice Site (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- NEXMIF | c.940T>C p.Y314H | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NTM | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NUDT3 | c.260A>T p.Q87L | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- OR4D6 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PABPC3 | c.675T>A p.D225E | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); called by muse, mutect2
- PCDH19 | c.479G>T p.S160I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2
- PIKFYVE | c.3834G>T p.M1278I | Missense Mutation (SNP) | VAF 28/507 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- PLXND1 | c.3800dup p.S1268Qfs*34 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by pindel, varscan2
- PPP1R8 | c.742G>A p.E248K (on ENST00000311772 / NM_014110.5; = p.E24K on NM_002713.4) | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2
- PRKG2 | c.937A>G p.I313V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.436); called by muse, mutect2
- SLC6A11 | c.1185G>T p.W395C | Missense Mutation (SNP) | VAF 49/694 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- TENM1 | c.2641T>A p.F881I | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2
- ZFHX4 | c.6529T>A p.F2177I | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- AP002512.3 | c.684C>A p.A228= | Silent (SNP) | VAF 8/135 reads (6%) | catalogued as COSV54408536; called by muse, mutect2
- CNTNAP5 | c.3162C>A p.L1054= | Silent (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- FAM47A | c.801G>A p.L267= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- OR5T2 | c.570T>A p.A190= | Silent (SNP) | VAF 11/216 reads (5%) | called by muse, mutect2
- SLC6A6 | c.546C>A p.V182= | Silent (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- MAGEC3 | c.1124-54C>A | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- TMEM183B | n.684C>T | RNA (SNP) | VAF 16/317 reads (5%) | called by muse, mutect2
